Gene-level copy-number profile of tumor specimen TCGA-HD-7754-01A from TCGA case TCGA-HD-7754, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 69.4 years (25,365 days).
Specimen TCGA-HD-7754-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.4bf38b06-371a-4c4e-9e59-bfa21bc28286.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HD-7754-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/77bd85a9-5014-48b6-99fd-374c168a5d12

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,471; copy number 2: 49,964; copy number 3: 2,625; copy number 4: 1,803; copy number 5: 48; copy number 6: 850; copy number 8: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HD-7754-01A-11D-2077-01): tumor purity 0.75, ploidy 2.12, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 949 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:161,083,883–167,653,983, 48 genes, copy number 5 (within-gene range 4–5): B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC112770.1, AC131211.1, TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49.
- chr12:66,767–34,249,958, 850 genes, copy number 6 (broad region; genes not listed).
- chr18:268,148–2,805,017, 51 genes, copy number 8 (within-gene range 4–16): AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3, AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1.

Autosomal genes at a single copy (total copy number 1): 2,090. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
